Somatic mutation profile of tumor specimen TCGA-AR-A24Z-01A (aliquot TCGA-AR-A24Z-01A-11D-A167-09) from TCGA case TCGA-AR-A24Z, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.2 years (20,900 days).
Specimen TCGA-AR-A24Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 803eb1cc-9f86-4123-a30c-5a6304224e7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A24Z-10A (Blood Derived Normal), aliquot TCGA-AR-A24Z-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c39902ac-2215-4d12-8214-3c801c3b5453

The open-access MAF lists 43 somatic variants for this specimen: 35 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 31, Silent 8, Frame Shift Del 2, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACKR4 | c.563T>C p.F188S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1221481797, COSV51442384; called by muse, mutect2, varscan2
- ADAMTS13 | c.565A>T p.N189Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63022833; called by muse, mutect2, varscan2
- ATP13A4 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55074065; called by muse, mutect2, varscan2
- COL4A4 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV61635672; called by muse, mutect2, varscan2
- DNAH11 | c.5125A>C p.T1709P | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.674); catalogued as COSV60975699; called by muse, mutect2, varscan2
- GINS3 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs757683781, COSV58920369; called by muse, mutect2, varscan2
- IDE | c.1929G>C p.K643N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV56426549; called by muse, mutect2, varscan2
- INHA | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs753969684, COSV54728409; called by muse, mutect2, varscan2
- LAP3 | c.472G>C p.G158R | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56901343; called by muse, mutect2, varscan2
- MANEA | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV62590427; called by muse, mutect2, varscan2
- MAP4K1 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV67712655; called by muse, mutect2, varscan2
- MED20 | c.458G>A p.C153Y | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54826179; called by muse, mutect2, varscan2
- MYH8 | c.797T>C p.I266T | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753890411, COSV67959487, COSV67970952; called by muse, mutect2, varscan2
- MYO3A | c.3359A>C p.D1120A | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.041); catalogued as COSV56345104; called by muse, mutect2, varscan2
- NEK5 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62880685; called by muse, mutect2, varscan2
- NFXL1 | c.2157G>T p.L719F | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as COSV61200369; called by muse, mutect2, varscan2
- NLK | c.225_242del p.A78_A83del | In Frame Del (DEL) | VAF 38/65 reads (58%) | catalogued as rs780017549; called by mutect2, pindel, varscan2
- NOX5 | c.1287G>T p.L429F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as COSV52994710; called by muse, mutect2, varscan2
- OR1A1 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs373533523, COSV58403892; called by muse, mutect2
- PDE10A | c.1811A>T p.Q604L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100604821; called by muse, mutect2
- PDE3A | c.2653T>A p.F885I | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62981039; called by muse, mutect2, varscan2
- PLXNB1 | c.3085T>A p.C1029S | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV56493479; called by muse, mutect2, varscan2
- PTPRB | c.4603G>T p.E1535* | Nonsense Mutation (SNP) | VAF 27/96 reads (28%) | catalogued as COSV54237080, COSV54250916; called by muse, mutect2, varscan2
- SCN1A | c.641C>A p.A214E | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57663649, COSV57683807; called by muse, mutect2, varscan2
- SKIL | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52062198; called by muse, mutect2, varscan2
- STOX1 | c.1030G>C p.V344L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53813077, COSV53817358; called by muse, mutect2, varscan2
- TTC7A | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544316606, COSV55408481; called by muse, mutect2, varscan2
- TTN | c.60498C>G p.C20166W (on ENST00000591111; = p.C12742W on NM_003319.4) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | PolyPhen probably damaging (0.975); catalogued as COSV60284212; called by muse, mutect2, varscan2
- TYRP1 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.156); catalogued as COSV101141241; called by muse, mutect2, varscan2
- ZNF425 | c.1748C>A p.A583E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1191022304, COSV65200604, COSV65202436; called by muse, mutect2, varscan2
- ZNF425 | c.652T>G p.C218G | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV65202442; called by muse, mutect2, varscan2
- ZNF496 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV54181345; called by muse, mutect2, varscan2
- GPR148 | c.205del p.L69Cfs*4 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- SPTA1 | c.4439_4442del p.D1480Gfs*9 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- TPTE | c.419A>G p.D140G (on ENST00000618007 / NM_199261.4; = p.D122G on NM_199259.4) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C1orf74 | c.768C>T p.S256= | Silent (SNP) | VAF 11/136 reads (8%) | catalogued as rs765387477, COSV50558518; called by muse, mutect2
- COL18A1 | c.39G>A p.L13= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV62706268; called by muse, mutect2, varscan2
- DEFB131A | c.27A>C p.G9= | Silent (SNP) | VAF 38/119 reads (32%) | catalogued as rs745737615, COSV58416682; called by muse, mutect2, varscan2
- EOLA1 | c.303C>G p.P101= | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as rs782752836, COSV63734049, COSV63734079, COSV63734090; called by muse, mutect2, varscan2
- ERCC6L | c.1623C>T p.V541= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs781419143, COSV57822109; called by muse, mutect2, varscan2
- FAM135B | c.213C>T p.V71= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV50536631; called by muse, mutect2
- IVL | c.705C>A p.L235= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV64216892; called by muse, varscan2
- RBBP4 | c.51C>T p.I17= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV59385603, COSV59386541; called by muse, mutect2, varscan2
